Somatic mutation profile of tumor specimen C3L-04245-54 (aliquot CPT0259920002) from CPTAC case C3L-04245, project CPTAC-3 (Hematopoietic and reticuloendothelial systems — Myeloid Leukemias). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 69.3 years (25,307 days).
Specimen C3L-04245-54: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 530d92b6-1aa7-4637-b47b-43f1ce253b05.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-04245-50 (Buccal Cell Normal), aliquot CPT0259910003; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8e0bc55c-d76b-42ee-a90e-16a34a5f388c

The open-access MAF lists 4 somatic variants for this specimen: 4 protein-altering or splice-affecting.
By variant classification: Missense Mutation 3, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EZH2 | c.2054G>A p.R685H (on ENST00000460911 / NM_001203247.2; = p.R690H on NM_004456.5) | Missense Mutation (SNP) | VAF 56/61 reads (92%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1554481435, COSV57446082; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- NRAS | c.182A>C p.Q61P | Missense Mutation (SNP) | VAF 42/83 reads (51%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.425); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- HPRT1 | c.146T>C p.L49P | Missense Mutation (SNP) | VAF 44/274 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM144794, CX150320; called by muse, varscan2
- NAV2 | c.1390del p.E464Sfs*35 (on ENST00000396087 / NM_001244963.2; = p.E441Sfs*35 on NM_145117.5) | Frame Shift Del (DEL) | VAF 31/77 reads (40%) | called by mutect2, pindel, varscan2
